Somatic mutation profile of tumor specimen ALCH-B2NN-TTP1-A (aliquot ALCH-B2NN-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2NN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.1 years (25,590 days).
Specimen ALCH-B2NN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e30fa239-8335-426a-a52d-537176aa9b20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2NN-NB1-A (Blood Derived Normal), aliquot ALCH-B2NN-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e9d46e2-2184-424d-bdf2-35e352fb2d9a

The open-access MAF lists 273 somatic variants for this specimen: 181 protein-altering or splice-affecting, 57 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 57, Intron 15, RNA 9, Nonsense Mutation 8, Splice Site 4, 3'Flank 4, 5'UTR 4, 3'UTR 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 35/193 reads (18%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSL6 | c.91G>A p.V31M (on ENST00000379240; = p.V56M on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs773584641, COSV57300833; called by muse, mutect2
- ADGRB3 | c.3607G>T p.D1203Y | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV53263801; called by muse, mutect2, varscan2
- ATG2B | c.5954A>T p.Q1985L | Missense Mutation (SNP) | VAF 39/361 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99951966; called by muse, mutect2, varscan2
- BEND2 | c.1601T>G p.L534R | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1017669230, COSV101192224, COSV66217216; called by muse, mutect2, varscan2
- BRIP1 | c.2330G>T p.R777L | Missense Mutation (SNP) | VAF 84/1095 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52002146; called by muse, mutect2
- C10orf90 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 44/453 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52949332, COSV99505386; called by muse, mutect2
- CLGN | c.1349T>C p.I450T | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs1446840911; called by muse, mutect2
- COL11A1 | c.2197-1G>A p.X733_splice | Splice Site (SNP) | VAF 57/1011 reads (6%) | catalogued as COSV100616486; called by muse, mutect2
- CPS1 | c.952C>A p.Q318K | Missense Mutation (SNP) | VAF 36/618 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1335664604; called by muse, mutect2
- EFCAB6 | c.3977G>T p.R1326L | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53067194; called by muse, mutect2, varscan2
- FCRL4 | c.1137G>C p.E379D | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs755630731; called by muse, mutect2
- FGB | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.655); catalogued as rs1319865641, COSV57417746; called by muse, mutect2
- GABRG2 | c.1513C>G p.L505V (on ENST00000361925 / NM_001375343.1; = p.L465V on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/525 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100729734; called by muse, mutect2
- HOXA4 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 16/228 reads (7%) | catalogued as COSV57826348; called by muse, mutect2
- IL9R | c.725C>A p.T242K | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs781726149; called by muse, mutect2
- ITIH2 | c.1630G>C p.V544L | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV64432312; called by muse, mutect2, varscan2
- KCNT2 | c.1263G>T p.K421N | Missense Mutation (SNP) | VAF 24/488 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV54062959; called by muse, mutect2
- LAMP3 | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV55614882, COSV55617138; called by mutect2, varscan2
- LRP1B | c.13262G>T p.W4421L | Missense Mutation (SNP) | VAF 60/850 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs752817139, COSV67199902; called by muse, mutect2
- MUC16 | c.27265A>G p.T9089A | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.028); catalogued as rs753252672, COSV67469598; called by muse, mutect2
- NPAS4 | c.1288C>G p.Q430E | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100215182; called by muse, mutect2
- NRXN3 | c.1675A>G p.S559G (on ENST00000557594 / NM_001272020.2; = p.S983G on NM_004796.6) | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as rs1390689222; called by muse, mutect2, varscan2
- OR2W1 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV65851491; called by muse, mutect2
- OR4F6 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 27/456 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs558260972, COSV100186931; called by muse, mutect2
- OR4K17 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs771503466; called by muse, varscan2
- PAPPA2 | c.4199T>A p.L1400Q | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.043); catalogued as COSV62791850, COSV62802287, COSV62808880; called by muse, mutect2
- PCDHA6 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 26/335 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.051); catalogued as COSV65352061; called by muse, mutect2
- POSTN | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 33/315 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs200308301, COSV65713236; called by muse, mutect2, varscan2
- PROS1 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.906); catalogued as COSV67777718; called by muse, mutect2
- RIMS2 | c.2690A>G p.Y897C (on ENST00000666250 / NM_001348490.2; = p.Y705C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/485 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs773050117; called by muse, mutect2
- RNF212 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV100381310; called by muse, mutect2, varscan2
- SALL1 | c.2248A>T p.K750* | Nonsense Mutation (SNP) | VAF 26/320 reads (8%) | catalogued as COSV99171540; called by muse, mutect2
- SLC24A5 | c.1072A>G p.I358V | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs1328472078; called by muse, mutect2
- SP9 | c.1252G>A p.G418S | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs1173690628; called by muse, mutect2
- SPTLC2 | c.44G>C p.R15P | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV53638482; called by muse, mutect2, varscan2
- STOX2 | c.677A>G p.Y226C | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV57855484; called by muse, mutect2
- SUN3 | c.123-1G>A p.X41_splice | Splice Site (SNP) | VAF 20/365 reads (5%) | catalogued as rs1305207935; called by muse, mutect2
- TIGIT | c.290C>G p.S97W | Missense Mutation (SNP) | VAF 17/269 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs376092576, COSV101048299; called by muse, mutect2
- TLNRD1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as rs1180079435, COSV99146103; called by muse, mutect2
- TTN | c.4613G>T p.R1538I (on ENST00000591111; = p.R1492I on NM_003319.4) | Missense Mutation (SNP) | VAF 30/468 reads (6%) | PolyPhen benign (0.186); catalogued as rs753961168, COSV60361507; called by muse, mutect2
- UNC93A | c.592C>A p.Q198K | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs764938594; called by muse, mutect2, varscan2
- UTP18 | c.568A>G p.M190V | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1352759861; called by muse, mutect2
- VIT | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 73/685 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs1353010094; called by muse, mutect2, varscan2
- WDR11 | c.1794G>T p.R598S | Missense Mutation (SNP) | VAF 61/867 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV54786571; called by muse, mutect2
- ZNF99 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.061); catalogued as COSV68055344, COSV68055640, COSV68056324; called by muse, mutect2
- AASS | c.2449G>T p.A817S | Missense Mutation (SNP) | VAF 64/816 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.223); called by muse, mutect2
- ACSM3 | c.1541C>G p.P514R | Missense Mutation (SNP) | VAF 48/666 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); called by muse, mutect2
- ACTBL2 | c.942G>T p.M314I | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ADAMTS12 | c.1528A>G p.K510E | Missense Mutation (SNP) | VAF 38/486 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- ADAMTS20 | c.1385G>A p.C462Y | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ADAMTS9 | c.3002G>T p.W1001L | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AKAP3 | c.695A>T p.D232V | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2
- AKAP6 | c.281A>T p.D94V | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALB | c.829T>A p.C277S | Missense Mutation (SNP) | VAF 74/958 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANKRD65 | c.58T>C p.W20R | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2
- ANKS1B | c.3247G>T p.D1083Y (on ENST00000547776 / NM_152788.4; = p.D249Y on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANPEP | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2
- ASPM | c.3736G>C p.E1246Q | Missense Mutation (SNP) | VAF 44/530 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2
- ATM | c.1313T>C p.I438T | Missense Mutation (SNP) | VAF 24/287 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2
- BPIFB3 | c.953C>A p.T318K | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2
- C20orf27 | c.442C>A p.P148T (on ENST00000379772 / NM_001258429.2; = p.P173T on NM_001039140.3) | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CBY2 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCBE1 | c.528G>C p.R176S | Missense Mutation (SNP) | VAF 23/442 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- CCDC141 | c.3909A>T p.R1303S | Missense Mutation (SNP) | VAF 24/434 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2
- CCDC144A | c.737A>T p.Q246L | Missense Mutation (SNP) | VAF 70/428 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC33 | c.2130A>G p.I710M | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.465); called by muse, mutect2
- CCL23 | c.164A>T p.Q55L | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.168); called by muse, mutect2
- CCN3 | c.173T>A p.L58Q | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.875); called by muse, mutect2
- CFAP161 | c.392G>T p.S131I | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2
- CHD7 | c.5560G>T p.D1854Y | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- CHST4 | c.629T>G p.V210G | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CIP2A | c.1830A>G p.V610= | Splice Region (SNP) | VAF 25/203 reads (12%) | called by muse, mutect2, varscan2
- CMPK2 | c.1184G>A p.R395K | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CNBD1 | c.1129G>C p.V377L | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.2); called by muse, mutect2
- COL22A1 | c.3845G>T p.G1282V | Missense Mutation (SNP) | VAF 21/385 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COMMD9 | c.158C>G p.T53S | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.085); called by muse, mutect2
- CPNE1 | c.574T>C p.F192L (on ENST00000352393; = p.F197L on NM_003915.5) | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.38); called by muse, mutect2
- CYFIP2 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CYTIP | c.760A>T p.T254S | Missense Mutation (SNP) | VAF 16/305 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, mutect2
- DCHS1 | c.6802A>T p.I2268F | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2
- DCLK1 | c.1096G>C p.D366H | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2
- DCLK3 | c.1355C>A p.P452H | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.006); called by muse, mutect2
- DFFA | c.475C>G p.Q159E | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.005); called by muse, mutect2
- DISP1 | c.2392A>C p.N798H | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- DNAH10 | c.12458G>T p.R4153L (on ENST00000409039; = p.R4092L on NM_207437.3) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAJC13 | c.2638G>C p.V880L | Missense Mutation (SNP) | VAF 41/538 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- EGF | c.1598T>A p.L533Q | Missense Mutation (SNP) | VAF 64/874 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.961); called by muse, mutect2
- EGLN2 | c.759T>G p.I253M | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- EXD2 | c.1453A>C p.I485L (on ENST00000312994 / NM_001193362.1; = p.I360L on NM_018199.3) | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2
- FGG | c.703A>T p.I235F | Missense Mutation (SNP) | VAF 46/590 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.386); called by muse, mutect2
- FSIP2 | c.17590C>T p.P5864S | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.034); called by muse, mutect2
- GJD2 | c.177G>C p.Q59H | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HACE1 | c.2385T>G p.D795E | Missense Mutation (SNP) | VAF 47/634 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2
- HNMT | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 24/526 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by muse, mutect2
- HSD11B1 | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 31/491 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- HSPG2 | c.9186G>T p.E3062D | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, varscan2
- IGKV1D-12 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 19/510 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.213); called by muse, mutect2
- IL1RAPL1 | c.2004G>T p.R668S | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IQCJ | c.378G>C p.K126N | Missense Mutation (SNP) | VAF 19/346 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.295); called by muse, mutect2
- JPH1 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 20/287 reads (7%) | called by muse, mutect2
- KLHL9 | c.1078A>G p.T360A | Missense Mutation (SNP) | VAF 39/547 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.9); called by muse, mutect2
- KRTAP10-2 | c.212G>T p.C71F | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- LACC1 | c.1175A>G p.Q392R | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.195); called by muse, mutect2
- LAMB4 | c.1321C>A p.H441N | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- LANCL3 | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.046); called by muse, mutect2
- LCT | c.4424G>C p.R1475T | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2
- LIN28A | c.214G>T p.V72F | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRP1B | c.3168T>A p.N1056K | Missense Mutation (SNP) | VAF 37/381 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- LYPD8 | c.541C>A p.L181M | Missense Mutation (SNP) | VAF 46/483 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAP3K15 | c.2342T>C p.V781A | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGAM | c.2129G>T p.R710M | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- MUC15 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 36/680 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.013); called by muse, mutect2
- MUC16 | c.8039C>A p.T2680K | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2
- MYH7 | c.1164G>A p.M388I | Missense Mutation (SNP) | VAF 20/303 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- MYLPF | c.104C>G p.T35S | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.183); called by muse, mutect2
- MYO6 | c.1163T>A p.V388E | Missense Mutation (SNP) | VAF 108/1066 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- NAV3 | c.2765C>G p.T922S | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NAV3 | c.4308C>A p.N1436K | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.05); called by muse, mutect2
- NECTIN2 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 18/303 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NELL1 | c.916A>G p.R306G | Missense Mutation (SNP) | VAF 37/811 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); called by muse, mutect2
- NET1 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); called by muse, mutect2
- NLRP5 | c.476C>A p.T159N | Missense Mutation (SNP) | VAF 16/361 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- NOL6 | c.364G>T p.V122F | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NSL1 | c.187G>C p.A63P | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2
- NUP188 | c.1807G>T p.V603L | Missense Mutation (SNP) | VAF 47/341 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- OR2AT4 | c.707T>C p.L236P | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2
- OR2M7 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 43/419 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4C6 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.035); called by muse, mutect2
- OR6S1 | c.248T>C p.M83T | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); called by muse, mutect2
- PIGK | c.239+1G>T p.X80_splice | Splice Site (SNP) | VAF 26/218 reads (12%) | called by muse, mutect2
- PIK3C2G | c.3810C>G p.N1270K (on ENST00000676171; = p.N1229K on NM_004570.5) | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- PKHD1L1 | c.2593C>G p.Q865E | Missense Mutation (SNP) | VAF 55/588 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- PLSCR2 | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- POP1 | c.1225C>G p.L409V | Missense Mutation (SNP) | VAF 36/351 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2
- PPIAL4C | c.38A>T p.D13V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); called by mutect2, varscan2
- PRG4 | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 84/984 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PROX2 | c.617A>C p.H206P | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- PRR23B | c.292A>T p.I98F | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- PSG1 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 27/833 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.217); called by muse, mutect2
- PTDSS1 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 44/333 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RAB3GAP2 | c.2310+1G>T p.X770_splice | Splice Site (SNP) | VAF 76/1041 reads (7%) | called by muse, mutect2
- RAB44 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 24/340 reads (7%) | called by muse, mutect2
- RIOX1 | c.143C>G p.S48C | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2
- RIOX2 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- RIPOR2 | c.679A>T p.M227L | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); called by muse, mutect2
- RSBN1 | c.1247A>G p.H416R | Missense Mutation (SNP) | VAF 40/694 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- RUNX3 | c.269C>G p.P90R | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); called by muse, mutect2
- RYR2 | c.12182C>G p.S4061* | Nonsense Mutation (SNP) | VAF 64/684 reads (9%) | called by muse, mutect2
- RYR3 | c.4198C>T p.Q1400* | Nonsense Mutation (SNP) | VAF 32/388 reads (8%) | called by muse, mutect2
- SAMD9 | c.4364A>T p.E1455V | Missense Mutation (SNP) | VAF 322/632 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- SATB2 | c.513C>A p.N171K | Missense Mutation (SNP) | VAF 44/636 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.416); called by muse, mutect2
- SCUBE2 | c.338G>T p.C113F | Missense Mutation (SNP) | VAF 32/462 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEPTIN12 | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- SERBP1 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 15/367 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2
- SHISA9 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SIK3 | c.1039A>T p.M347L (on ENST00000445177 / NM_001366686.2; = p.M353L on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/395 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.065); called by muse, mutect2
- SLC25A6 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.358); called by muse, mutect2
- SLC30A7 | c.302T>A p.V101D | Missense Mutation (SNP) | VAF 65/703 reads (9%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.96); called by muse, mutect2
- SLC39A1 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- SLC6A1 | c.1561C>A p.P521T | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- SLC8A3 | c.2351G>T p.G784V (on ENST00000381269 / NM_183002.3; = p.G782V on NM_033262.4) | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC9A3R1 | c.1068C>A p.S356R | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SSR4 | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SULT1C2 | c.56C>G p.T19S | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2
- SYNE2 | c.16054G>T p.A5352S | Missense Mutation (SNP) | VAF 107/1220 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.1); called by muse, mutect2
- TECRL | c.348G>T p.K116N | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.23); called by muse, mutect2
- TLR3 | c.2539A>G p.I847V | Missense Mutation (SNP) | VAF 41/454 reads (9%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.557); called by muse, mutect2
- TMPRSS11A | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0.007); called by muse, mutect2
- TRGV5 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- UFL1 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 36/441 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, mutect2
- UGT3A2 | c.697T>G p.S233A | Missense Mutation (SNP) | VAF 38/650 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.083); called by muse, mutect2
- VPS13A | c.846G>C p.E282D | Missense Mutation (SNP) | VAF 67/671 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR81 | c.1608G>T p.E536D | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- WRN | c.249G>C p.M83I | Missense Mutation (SNP) | VAF 75/964 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- WSCD1 | c.1108C>A p.L370I | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- XPO7 | c.3148C>A p.L1050I | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2
- ZNF277 | c.985C>G p.L329V | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2
- ZNF521 | c.3690C>A p.C1230* | Nonsense Mutation (SNP) | VAF 44/549 reads (8%) | called by muse, mutect2
- ZNF701 | c.1276G>A p.D426N (on ENST00000301093; = p.D360N on NM_018260.3) | Missense Mutation (SNP) | VAF 32/743 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); called by muse, mutect2
- ZNF880 | c.844C>G p.H282D | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.112); called by muse, mutect2
- A4GALT | c.165G>T p.L55= | Silent (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- ABCA13 | c.13758C>A p.T4586= | Silent (SNP) | VAF 27/270 reads (10%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1185G>T p.V395= | Silent (SNP) | VAF 10/256 reads (4%) | called by muse, mutect2
- ANK2 | c.1398G>C p.T466= | Silent (SNP) | VAF 45/700 reads (6%) | called by muse, mutect2
- BIRC6 | c.13338C>G p.T4446= | Silent (SNP) | VAF 43/409 reads (11%) | called by muse, mutect2, varscan2
- C8orf34 | c.795G>T p.L265= | Silent (SNP) | VAF 14/211 reads (7%) | called by muse, mutect2
- CCDC141 | c.936A>T p.A312= | Silent (SNP) | VAF 22/294 reads (7%) | called by muse, mutect2
- CCDC168 | c.12534A>C p.A4178= | Silent (SNP) | VAF 16/503 reads (3%) | called by muse, mutect2
- CCIN | c.1083G>A p.L361= | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- CDC42EP2 | c.180C>T p.G60= | Silent (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- CDH10 | c.2064A>T p.R688= | Silent (SNP) | VAF 74/861 reads (9%) | called by muse, mutect2
- CMTM4 | c.345G>A p.Q115= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV58062577; called by muse, mutect2
- CNOT4 | c.315C>T p.V105= | Silent (SNP) | VAF 36/538 reads (7%) | catalogued as rs769577153; called by muse, mutect2
- COL25A1 | c.426G>A p.Q142= | Silent (SNP) | VAF 18/354 reads (5%) | catalogued as COSV101211422; called by muse, mutect2
- CPS1 | c.3021C>T p.G1007= | Silent (SNP) | VAF 42/485 reads (9%) | called by muse, mutect2
- CRB1 | c.2910C>A p.T970= | Silent (SNP) | VAF 32/308 reads (10%) | called by muse, mutect2
- CRMP1 | c.933T>A p.P311= | Silent (SNP) | VAF 11/161 reads (7%) | called by muse, mutect2
- DEUP1 | c.364C>A p.R122= | Silent (SNP) | VAF 22/438 reads (5%) | catalogued as rs566601356, COSV53210337; called by muse, mutect2
- FASTKD1 | c.207A>T p.G69= | Silent (SNP) | VAF 39/429 reads (9%) | catalogued as rs1362230808; called by muse, mutect2
- FAT1 | c.12249T>C p.T4083= | Silent (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- FOXI3 | c.873G>A p.P291= | Silent (SNP) | VAF 32/231 reads (14%) | catalogued as rs201502447, COSV67916666; called by muse, mutect2, varscan2
- FSIP2 | c.7665G>A p.V2555= | Silent (SNP) | VAF 20/236 reads (8%) | catalogued as COSV100553641; called by muse, mutect2
- FTO | c.1332A>T p.A444= | Silent (SNP) | VAF 36/849 reads (4%) | called by muse, mutect2
- GAB4 | c.513C>A p.G171= | Silent (SNP) | VAF 11/129 reads (9%) | called by muse, mutect2
- GP5 | c.135G>T p.A45= | Silent (SNP) | VAF 21/148 reads (14%) | called by muse, mutect2, varscan2
- HECW1 | c.1329C>G p.A443= | Silent (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- HLA-DOA | c.369G>A p.V123= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as rs1377480512, COSV57713644; called by muse, mutect2
- ICMT | c.828C>T p.F276= | Silent (SNP) | VAF 6/61 reads (10%) | called by muse, varscan2
- KIF18A | c.2019A>T p.P673= | Silent (SNP) | VAF 39/366 reads (11%) | catalogued as COSV54186514; called by muse, mutect2, varscan2
- KIF26A | c.2382G>T p.G794= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- MUCL3 | c.456C>G p.S152= | Silent (SNP) | VAF 15/159 reads (9%) | called by muse, mutect2
- OOSP1 | c.171A>T p.L57= | Silent (SNP) | VAF 49/675 reads (7%) | called by muse, mutect2
- OR6F1 | c.660C>T p.Y220= | Silent (SNP) | VAF 23/255 reads (9%) | called by muse, mutect2
- PATL2 | c.129G>A p.E43= | Silent (SNP) | VAF 29/265 reads (11%) | catalogued as rs1417334009; called by muse, mutect2, varscan2
- PCDHB8 | c.1974G>T p.T658= | Silent (SNP) | VAF 10/244 reads (4%) | called by muse, mutect2
- PNMA8B | c.936G>A p.S312= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV66537440; called by muse, mutect2, varscan2
- PSMA5 | c.489A>G p.V163= | Silent (SNP) | VAF 22/488 reads (5%) | called by muse, mutect2
- R3HDM2 | c.2301C>T p.T767= | Silent (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- RBAK | c.552G>T p.G184= | Silent (SNP) | VAF 28/288 reads (10%) | called by muse, mutect2
- RORC | c.561C>T p.S187= | Silent (SNP) | VAF 28/173 reads (16%) | called by muse, mutect2, varscan2
- RXRB | c.120G>A p.R40= | Silent (SNP) | VAF 8/192 reads (4%) | catalogued as rs1239155172; called by muse, mutect2
- RYR2 | c.5796T>C p.F1932= | Silent (SNP) | VAF 47/518 reads (9%) | called by muse, mutect2
- SLC12A3 | c.165C>T p.T55= | Silent (SNP) | VAF 32/422 reads (8%) | catalogued as rs1411056528; called by muse, mutect2
- SLC26A7 | c.579A>G p.S193= | Silent (SNP) | VAF 22/418 reads (5%) | called by muse, mutect2
- SLC2A13 | c.1527A>G p.A509= | Silent (SNP) | VAF 44/628 reads (7%) | catalogued as COSV55116411; called by muse, mutect2
- SNX14 | c.2469G>T p.L823= (on ENST00000314673 / NM_001350535.1; = p.L770= on NM_020468.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 20/296 reads (7%) | called by muse, mutect2
- SPATA31E1 | c.2719A>C p.R907= | Silent (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2
- SREBF2 | c.2406C>G p.A802= | Silent (SNP) | VAF 27/462 reads (6%) | catalogued as rs557048134; called by muse, mutect2
- ST7L | c.45G>C p.A15= | Silent (SNP) | VAF 11/153 reads (7%) | catalogued as COSV54144854; called by muse, mutect2
- TMEM132E | c.127C>T p.L43= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as rs1174230577; called by muse, mutect2
- TRIM48 | c.432C>G p.P144= | Silent (SNP) | VAF 56/562 reads (10%) | called by muse, mutect2
- TRIM64 | c.729G>C p.L243= | Silent (SNP) | VAF 27/232 reads (12%) | called by muse, mutect2, varscan2
- TRPC6 | c.1092C>T p.S364= | Silent (SNP) | VAF 40/720 reads (6%) | catalogued as COSV100723594; called by muse, mutect2
- UMAD1 | c.216A>T p.A72= | Silent (SNP) | VAF 26/403 reads (6%) | called by muse, mutect2
- USH2A | c.10230A>T p.T3410= | Silent (SNP) | VAF 32/348 reads (9%) | called by muse, mutect2
- WDR62 | c.1050C>G p.L350= | Silent (SNP) | VAF 19/278 reads (7%) | catalogued as rs776125890; called by muse, mutect2
- ZFHX4 | c.576C>A p.I192= | Silent (SNP) | VAF 16/288 reads (6%) | catalogued as COSV51455926, COSV99262351; called by muse, mutect2
- ADAM10 | c.207-8848A>G | Intron (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2, varscan2
- AGAP7P | n.991G>C | RNA (SNP) | VAF 28/554 reads (5%) | called by muse, mutect2
- AMPH | c.1182+728A>G | Intron (SNP) | VAF 30/516 reads (6%) | catalogued as rs556116446; called by muse, mutect2
- AP002008.2 | n.1079C>T | RNA (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- ARHGEF25 | chr12:57619756 C>T | 3'Flank (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- B2M | c.-18G>A | 5'UTR (SNP) | VAF 22/378 reads (6%) | called by muse, mutect2
- CCDC171 | c.3600+8467G>A | Intron (SNP) | VAF 16/240 reads (7%) | called by muse, mutect2
- CCNYL2 | n.1005C>A | RNA (SNP) | VAF 31/410 reads (8%) | catalogued as rs1412521444; called by muse, mutect2
- CDKL2 | c.1416+3998C>G | Intron (SNP) | VAF 25/274 reads (9%) | called by muse, mutect2
- DACH2 | c.1751-4307T>C | Intron (SNP) | VAF 54/378 reads (14%) | called by muse, varscan2
- DPY30 | chr2:32023713 C>A | 3'Flank (SNP) | VAF 20/470 reads (4%) | called by muse, mutect2
- EDRF1 | c.1017-12G>C | Intron (SNP) | VAF 15/244 reads (6%) | called by muse, mutect2
- EIF3E | c.*25A>C | 3'UTR (SNP) | VAF 40/241 reads (17%) | called by muse, mutect2, varscan2
- ERBB4 | c.*18T>C | 3'UTR (SNP) | VAF 13/292 reads (4%) | called by muse, mutect2
- HLA-DQA1 | c.82+1427A>G | Intron (SNP) | VAF 22/424 reads (5%) | catalogued as rs1416402521; called by muse, mutect2
- HOXB3 | c.-179C>T | 5'UTR (SNP) | VAF 46/538 reads (9%) | called by muse, mutect2
- HSP90AA4P | n.1028C>G | RNA (SNP) | VAF 27/658 reads (4%) | called by muse, mutect2
- IGLV7-46 | c.-17C>T | 5'UTR (SNP) | VAF 23/301 reads (8%) | called by muse, mutect2
- ITK | c.985+37G>A | Intron (SNP) | VAF 26/294 reads (9%) | called by muse, mutect2
- LAIR2 | c.-2C>A | 5'UTR (SNP) | VAF 14/138 reads (10%) | catalogued as COSV100003272; called by mutect2, varscan2
- LAMB3 | c.2702-50C>T | Intron (SNP) | VAF 11/172 reads (6%) | called by muse, mutect2
- MCM5 | c.167+836A>G | Intron (SNP) | VAF 21/191 reads (11%) | called by muse, mutect2
- MED25 | chr19:49838609 C>T | 3'Flank (SNP) | VAF 45/425 reads (11%) | catalogued as rs747529507; called by muse, mutect2, varscan2
- Metazoa_SRP | chr17:18610116 G>T | 5'Flank (SNP) | VAF 160/2053 reads (8%) | called by muse, mutect2
- OFCC1 | n.149A>G | RNA (SNP) | VAF 18/260 reads (7%) | catalogued as rs777911779; called by muse, mutect2
- PLP1 | c.453+59T>C | Intron (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2
- SGIP1 | c.1571-45C>T | Intron (SNP) | VAF 36/538 reads (7%) | catalogued as rs745853670; called by muse, mutect2
- SIGLEC17P | n.1149A>T | RNA (SNP) | VAF 16/282 reads (6%) | called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-23927C>T | Intron (SNP) | VAF 22/412 reads (5%) | catalogued as COSV101042720; called by muse, mutect2
- SPATA8 | n.758C>A | RNA (SNP) | VAF 14/209 reads (7%) | called by muse, mutect2
- TPM1 | c.492+41T>A | Intron (SNP) | VAF 20/300 reads (7%) | called by muse, mutect2
- TRPV2 | chr17:16441310 C>G | 3'Flank (SNP) | VAF 33/184 reads (18%) | called by muse, mutect2, varscan2
- TUBB7P | n.838C>T | RNA (SNP) | VAF 16/176 reads (9%) | catalogued as rs1342009162; called by muse, mutect2, varscan2
- TXLNGY | n.322G>A | RNA (SNP) | VAF 69/437 reads (16%) | called by muse, mutect2, varscan2
- WDR45B | c.68-41C>T | Intron (SNP) | VAF 46/392 reads (12%) | called by muse, mutect2, varscan2
